Somatic mutation profile of tumor specimen 0DHPK3 from CCDI case PBBSER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (469 days).
Specimen 0DHPK3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a69377f-9424-42d3-af99-9648731a0a4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHPJB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2df55aec-32ad-4878-acec-2e49bcf0d0cf

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4022G>C p.R1341P | Missense Mutation (SNP) | VAF 85/647 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs587783488, COSV52128981, COSV52144912; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GCH1 | c.*40G>A | 3'UTR (SNP) | VAF 56/888 reads (6%) | catalogued as rs376668776; called by muse, mutect2
